FM case AD2826 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/2c2ea2e4-9bc9-4241-82ce-a0f1ed18bbd8

Male, 49.2 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
